Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4818, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4818-01A (Primary Tumor).

FINAL DIAGNOSIS

KIDNEY, RIGHT, RADICAL NEPHRECTOMY –

- A. RENAL CELL CARCINOMA (9.7 CM), CONVENTIONAL (CLEAR CELL) TYPE, FUHRMAN NUCLEAR GRADE 3 OF 4.
(see comment)
- B. TUMOR DOES NOT EXTEND BEYOND GEROTA'S FASCIA.
- C. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF TUMOR.
- D. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- E. NON-NEOPLASTIC KIDNEY SHOWS FOCAL INTERSTITIAL CHRONIC INFLAMMATION.
- F. TNM PATHOLOGIC STAGE = p T2 NX MX.
- G. TNM HISTOLOGIC GRADE = G3.

COMMENT:

Although large areas of carcinoma are composed of tumor cells with Fuhrman's nuclear grade 1 and 2, grade 3 areas with adjacent tumor necrosis are clearly identified.

Source: NCI Genomic Data Commons file ab2d324f-a16d-4410-8488-cb68526e6a27 (TCGA-B0-4818.960BDAE7-60B9-4693-9AF5-9AB8D2C40BD5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).